Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88Q, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88Q-01A (Primary Tumor).

[page 1 of 4]
Gender: Male	Birth Date	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
Surgical Pathology CASE NUMBER: DIAGNOSIS:	Final

1. Prostate, left apex, margin, resection: Fibromuscular tissue and vessel. No tumor seen.
2. Prostate, prostatectomy: Adenocarcinoma Gleason Score 8 (4+4) involving 25% of the right and 10% of the left lobes. The tumor has focal morphologic features of prostatic duct carcinoma and mixed with acinar and glandular areas. Perineural invasion is present. No extracapsular or seminal vesicle invasion is seen. Inked margins are negative for tumor.
3. Lymph nodes, anterior prostate fat, resection: Fibroadipose tissue. No tumor seen.
4. Lymph nodes, obturator, left, resection: Lymph nodes (0/4). No tumor seen.
5. Lymph nodes, obturator, right, resection: Lymph nodes (0/8). No tumor seen.
6. Prostate, adjacent to side of bladder, resection: Fibroadipose tissue. No tumor seen.

NOTE:

CAP Cancer Protocol:

Procedure: Radical prostatectomy

Prostate Size:
Weight: 36.2 g
Size: 4.5 x 3.0 x 4.0 cm

Lymph Node Sampling: Pelvic lymph node dissection

Histologic Type: Adenocarcinoma (acinar), Prostatic duct adenocarcinoma

Histologic Grade:
Primary Pattern: Grade 4
Secondary Pattern: Grade 4
Total Gleason Score: 8

Tumor Quantitation: Proportion (percentage) of prostate involved by tumor: 35%

Extraprostatic Extension: Not identified
Seminal Vesicle Invasion: Not identified

Margins: Margins uninvolved by invasive carcinoma

ICD-O-3
Adenocarcinoma, acinar
8140/3
Site: Prostate NOS
C61.9
Site 11/12/13

[page 2 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
---------------------------	----------------------

Treatment Effect on Carcinoma: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Present

Pathologic Staging (pTNM):

Primary Tumor (pT):

pT2c: Bilateral disease

Regional Lymph Nodes (pN):

pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined: 12

Number of Lymph Nodes Involved: 0

Distant Metastasis (pM): Not applicable

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: male with Gleason 8

PCa. Specimen Taken

For Protocol: Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: uncomplicated RARP and PLND

Post-Operative

Diagnosis: same Pre-Operative Diagnosis: Prostate Cancer

SPECIMENS SUBMITTED: 1. ROUTINE + 5FR.SLIDES, Left apex prostate margin (1FS)

2. PROSTATE

3. LYMPH NODES, Fat over anterior prostate

4. OBTURATOR LYMPH NODE(S), Left

5. OBTURATOR LYMPH NODE(S), Right

6. PROSTATE, Adjacent to side side of bladder

INTRAOPERATIVE CONSULTATION:

"Left apex prostate margin"

1FS diagnosis: Smooth muscle tissue, blood vessel with small nerve.

No prostate or other epithelia. No tumor seen in the five sections observed.

GROSS DESCRIPTION: Received fresh from the labeled with the patient's name the patient's medical record number

[page 3 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology	Final Results
---------------------------	----------------------

the patient's date of birth and further specified as:

1. "Left apex prostate margin" is a pink-red soft tissue fragment measuring 0.2 cm in greatest dimension. It was frozen in total for intraoperative consultation and then placed into a white cassette labeled as 1FS with the patient's name and sent to for permanent processing. Received in is a container with a specimen matching the above description. The entire contents were transferred from the green cassette and transferred to an orange cassette labeled as and submitted for permanent processing.

2. "Prostate" consists of a prostatectomy specimen weighing 36.2 grams with the following measurements:
Left to right: 4.5 cm
Anterior to posterior: 3.0 cm
Apex to base: 4.0 cm
Left seminal vesicle: 4.0 x 1.1 x 0.5 cm
Left vas deferens: 4.2 x 0.5 cm
Right seminal vesicle: 4.2 x 1.0 x 0.6 cm
Right vas deferens: 6.6 x 0.6 cm

The prostate is inked as follows: Urethra in yellow, anterior one-third in black, right posterior two thirds in blue, and left posterior two thirds in red. Gross photographs are taken. One cut is made revealing a tan nodular cut surface and a hard yellow-tan area in the apical periphery measuring 1.4 x 0.9 cm. Approximately 1.0 x 0.6 x 0.2 cm of tissue from the right apical peripheral, approximately 0.6 x 0.6 x 0.2 cm of tumor from the right apical peripheral, approximately 1.0 x 0.6 x 0.2 cm of normal-appearing prostatic tissue from the right mid are procured for the by . The procurement was documented/performed by and on at . Received in is the formalin-filled container with a specimen matching the above description. The seminal vesicles and vas deferens are dissected off the main prostate specimen. A whole mount generated through prior imaging is brought to the . The prostate is placed in the whole mount. Serial sections are made and are placed into white biopsy bags labeled 2F. The vas deferens and seminal vesicles, left and right, are sectioned and placed into white cassettes labeled 2G and 2H, while the left vas deferens and seminal vesicles are serially sectioned and placed into white cassettes labeled and 2K, while the right seminal vesicle and vas deferens are serially sectioned and placed into white cassettes labeled

3. "Fat and lymph node over anterior prostate" is a soft irregular yellow soft tissue fragment measuring 2.6 x 3.1 x 1.1 cm. The specimen is examined for candidate lymph nodes and no candidate lymph nodes are detected. The entirety of the remaining fibrofatty tissue is entirely placed into a white cassette labeled

[page 4 of 4]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology	Final Results
---------------------------	----------------------

4. "Left obturator lymph node" is a yellow fatty soft tissue fragment measuring 2.6 x 2.4 x 1.8 cm. The specimen is examined for candidate lymph nodes and 2 candidate lymph nodes are identified. One measures 2.4 cm and the other is 1.0 cm. They are both placed into a white cassette labeled . The remaining fibroadipose tissue is entirely placed into a white cassette labeled

5. "Right obturator lymph node" is a soft and rubbery yellow fatty tissue fragment measuring 6.4 x 5.5 x 2.4 cm. The specimen is inked for candidate lymph nodes and 7 candidate lymph nodes are identified. They range in size from 1.9 to 0.5 cm. Three of the larger lymph nodes are placed into a white cassette labeled while the remaining are placed into a white cassette labeled . The remaining fibroadipose tissue are entirely submitted in white cassettes labeled and 5E.

6. "Prostate adjacent to right side of bladder" are 3 tan and brown rubbery tissue fragments, irregular in shape, measuring 1.7 x 1.1 x 0.6 cm, 0.6 x 0.3 x 0.3 cm, and 1.4 x 0.5 x 0.6 cm. The largest fragment is bisected revealing a granular white firm cut surface. The entirety of the specimens are placed into a white cassette labeled

All cassettes were submitted for permanent processing.

Gross Description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Local/Synchronous Lesions Noted		
Case 1: (circle)		

3/31/14

10/23/13

Source: NCI Genomic Data Commons file a5de179a-5dda-47a1-bc0c-52265eec7dc6 (TCGA-VN-A88Q.AE58388B-52DC-41AD-A169-7E206BD6DE4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).